Somatic mutation profile of tumor specimen MMRF_2653_1_BM_CD138pos (aliquot MMRF_2653_1_BM_CD138pos_T1_KHS5U_L14264) from MMRF case MMRF_2653, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.9 years (19,317 days).
Specimen MMRF_2653_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8542b54c-0194-4f69-bab9-e2cf9c232bf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2653_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2653_1_PB_WBC_C3_KHS5U_L14265; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dbd6d2f-986a-416d-ac08-917484dbe1fa

The open-access MAF lists 53 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 12, 3'UTR 9, Silent 5, 5'UTR 3, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 82/261 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN1B | c.410del p.P137Rfs*8 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as rs1328655695, COSV99964122; called by mutect2, pindel, varscan2
- KSR2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs762058476, COSV60372403; called by muse, mutect2, varscan2
- MUC16 | c.4456T>C p.F1486L | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as rs762379793; called by muse, mutect2, varscan2
- MUC17 | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 213/595 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as COSV60307795; called by muse, mutect2, varscan2
- NAALADL2 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1383572035; called by muse, mutect2, varscan2
- NCKAP5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748072988; called by muse, mutect2, varscan2
- PRKDC | c.7219G>C p.G2407R | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100039161; called by muse, mutect2
- SLC6A14 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781971522, COSV64141427; called by muse, mutect2, varscan2
- ATL1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- BLVRA | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT16 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GDF2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GHSR | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA9 | c.544T>G p.L182V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ITGAV | c.2112C>A p.N704K | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFE2L3 | c.1475A>C p.Q492P | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51A7 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 189/438 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PEX12 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.072); called by muse, mutect2
- PRRC2A | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- TSPAN16 | c.483T>G p.D161E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TYK2 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFP64 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- EPHA3 | c.2085T>C p.V695= | Silent (SNP) | VAF 5/111 reads (5%) | called by muse, mutect2
- FHL2 | c.33C>T p.N11= | Silent (SNP) | VAF 141/373 reads (38%) | catalogued as rs760104483; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGLV4-3 | c.138G>A p.E46= | Silent (SNP) | VAF 91/187 reads (49%) | catalogued as rs758104470; called by muse, mutect2, varscan2
- OR5R1 | c.147C>T p.I49= | Silent (SNP) | VAF 36/500 reads (7%) | called by muse, mutect2
- RBM19 | c.252C>T p.A84= | Silent (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- AC092042.3 | c.277+37205G>A | Intron (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- CDH23 | c.3369+932C>T | Intron (SNP) | VAF 39/121 reads (32%) | catalogued as rs765788505; called by muse, mutect2, varscan2
- COBLL1 | c.344+62G>T | Intron (SNP) | VAF 22/88 reads (25%) | called by mutect2, varscan2
- DST | c.21609+47del | Intron (DEL) | VAF 16/37 reads (43%) | catalogued as rs768292616; called by mutect2, varscan2
- EMID1 | c.404-59G>A | Intron (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- FOXP2 | c.169-35464A>T | Intron (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- HYDIN | c.1738+3935T>C | Intron (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- JMJD1C | c.-82C>T | 5'UTR (SNP) | VAF 131/286 reads (46%) | catalogued as COSV101232406; called by muse, mutect2, varscan2
- KCNS2 | c.*396C>T | 3'UTR (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- LNPEP | c.*5793dup | 3'UTR (INS) | VAF 14/50 reads (28%) | catalogued as rs1414156079; called by mutect2, pindel, varscan2
- LYSMD3 | c.-144A>G | 5'UTR (SNP) | VAF 32/67 reads (48%) | catalogued as rs981489108; called by muse, mutect2, varscan2
- MGAT5B | c.1025+7540G>A | Intron (SNP) | VAF 29/235 reads (12%) | called by muse, mutect2, varscan2
- MOB1A | chr2:74178892 A>G | 5'Flank (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- PCDH19 | c.-435C>T | 5'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- PPIC | c.*85A>T | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- RAB39A | c.*942G>A | 3'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs1041398113; called by muse, mutect2, varscan2
- RCCD1 | c.*331T>G | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-915G>T | Intron (SNP) | VAF 60/132 reads (45%) | called by muse, mutect2, varscan2
- SERP1 | c.160+75T>A | Intron (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- SERPINA1 | c.-4-112C>A | Intron (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- SSH2 | c.*1884G>A | 3'UTR (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- STXBP5L | c.*5044G>T | 3'UTR (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- TBC1D20 | c.*692C>A | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- TMEM236 | c.*3259C>T | 3'UTR (SNP) | VAF 47/318 reads (15%) | called by muse, mutect2, varscan2
- VGLL4 | c.65-41494G>A | Intron (SNP) | VAF 89/295 reads (30%) | catalogued as COSV56080665; called by muse, mutect2, varscan2
